Surgical pathology report (de-identified scan), TCGA case TCGA-66-2778, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2778-01A (Primary Tumor).

[page 1 of 2]
Clinical diagnosis and question

Space-occupying lesion, left lower lobe, S10 and suspected mediastinal lymph node metastases.

REPORT ON FINDINGS

Macroscopy

- 1.) Hilar LN (station 10) left: 1 cm already incised node, section surfaces grayish-brown.
- 2.) Hilar LN (station 10) left: 1.5 cm node with surrounding tissue, section surfaces grayish-vitreous, patchy blackish pigmentation.
- 3.) Left lower lobe: inflated, fixed lower lobe measuring 10 x 7.5 cm at the base and up to 14 cm high, central bronchus resection plane located at the bifurcation into B6 and bronchi of the lower group. Lesioned bronchus in the region of the bifurcation of the segments of the lower group. At the hilus are four lesioned nodes between 0.5 cm and 2.4 cm. A staple suture line runs 9 cm from the hilus in a ventrocaudal direction. Visceral pleura appears turbid and cloudy, focal whitish thickening, in parts with delicate reticulate or patchy blackish pigmentation, bloody coating in the medial region and with deep retractions at the dorsal and basal margin laterally and relatively marked deformation of the lower lobe. Parietal pleura in the dorsomedial region over S10 shows an area of adhesion measuring 4 x 2 cm. Below this is a partly firm grayish-vitreous, fine patchy blackish pigmented, otherwise soft pale yellowish tumor, max. 6.5 cm in size, with arcuate contours, the main mass being located in S10, extending to adjacent sections of S 6 and 9. Intermediate and peripheral branches of B 9 and 10 leading to the tumor. Central tumor extension within 1.3 cm of the bronchus resection plane. Central parabronchial blackish node 0.8 cm in size at the tumor margin. The parenchyma surrounding the tumor shows slight focal compaction, with fine yellow patches. The remaining parenchyma shows small patches of slightly blackish pigmentation.
- 4.) Pleura: a fatty tissue measuring 8.5 x 2 cm, up to 0.3 cm thick, with predominantly shiny surfaces. One side a few plaques or lumps up to 0.1 cm in size.
- 5.) Lobar LN (station 12) left upper lobe: 2.3 cm lesioned node.
- 6.) Interlobar LN (station 11): 1.1 cm node.
- 7.) Pulmonary ligament LN (station 9): 1.7 cm node with some surrounding tissue. Including 0.7 cm fatty tissue.
- 8.) Paraesophageal LN (station 8): 0.5 cm node with abundant surrounding tissue.
- 9.) Paraaortic LN (station 6): 1 cm node.
- 10.) Subaortic LN (aortopulmonary window) (station 5): 1.7 cm lesioned node and a 1 cm flat fatty tissue specimen.
- 11.) Subcarinal LN (station 7): 1.1 cm node and a 0.8 cm node with abundant surrounding tissue.
- 12.) Hilar LN (station 10) right: 1.7 cm node.

Examined:

- 1.) + 2.) Rapid section remains and residual nodes
- 3.) 1 section of tumor with visceral pleura, 1 section of tumor with surrounding yellowish parenchyma, 2 sections of tumor central with nodes and bronchus, bronchial and vascular resection margins (tangential) and also smaller hilar nodes, largest hilar node, 2 sections of tumor with parietal pleura,
- 4.) 6 sections,
- 5.) - 12.) All material (in 5.), 7.) + 10.) lamellated in each case),
18 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

[page 2 of 2]
Microscopy

Re 1.) Immediate intraoperative evaluation (): lymph nodes in the samples examined show no evidence of carcinoma. After paraffin embedding:

Lymph nodes with intact underlying structure and inconspicuous cell content with formation of activated follicles.

Re 2.) Immediate intraoperative evaluation (): lymph node involvement by a large-cell solid carcinoma, possibly squamous cell differentiation. After paraffin embedding:

Lymph nodes with extensive infiltration by atypical epithelia arranged in partly branched solid structures. Predominantly moderately wide, partly elongated, moderately eosinophilic cytoplasm. Nuclei moderately anisomorphic and with enlarged chromatin. Predominantly small nucleoli. Centrally small necroses in parts with dense granulocytic infiltrates. Desmoplastic stroma around the atypical epithelia. Capsule of the lymph node partly enlarged by fibrosis.

Re 3.) Tumor made up of the atypical epithelia largely described in 2.). Focally enlarged cytoplasm and vaguely concentric position as well as focally identifiable intercellular bridges. Nuclei in part markedly anisomorphic. Extension of atypical epithelia initially as far as the visceral pleura in the region of the pleural adhesion zone. A hilar lymph node partly infiltrated by the atypical epithelia.

Parietal pleura, resection margin of bronchus and vessels and also small parabronchial nodes tumor-free. At the tumor margin lung tissue with macrophages that have transformed into foam cells, densely packed in some cases, with a smaller number of lymphocytes and granulocytes and focally also buds of mesenchyma partly incorporated in the wall and slightly collagenized. Alveolar septa partly enlarged and slightly to moderately infiltrated predominantly with lymphomonocytes.

Re 4.) Superficially focally preserved flat to cubic mesothelia. Underlying focal to moderately wide, vascularized fibrous tissue. Adjacent broad fatty tissue.

Re 5) and 12) Lymph nodes with focal infiltration by the atypical epithelia described in 2.) and 3).

Re 6.) - 11.) Lymph nodes as described for 1.).

EVALUATION

Primary diagnosis/diagnoses:

Peripheral to intermediate bronchopulmonary, histologically poorly differentiated, large-cell, nonkeratinizing squamous cell carcinoma of the left lower lobe of the lung with main location in S10.

TNM classification according to this picture pT2 pN3 pMX R0, stage IIIB.

C 34.3 M 807013.

Secondary diagnosis/diagnoses:

Lymph nodes with uncharacteristic reactive lesions (samples 1.) and 6.) - 11.)). Active chronic organizing retention pneumonia at the tumor margin. Pleural adhesion (sample 3.)). Resection material shows focal parietal pleura slightly enlarged with fibrosis (sample 4.)).

Remark/addendum:

None.

Source: NCI Genomic Data Commons file b22e8a08-12f9-4fa7-89cc-99b49f195bd3 (TCGA-66-2778.B4DDC4FA-5416-4A8B-8187-B328DBC0B946.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).